Gene-level copy-number profile of tumor specimen C3N-01346-03 (profiled together with C3N-01346-04) from CPTAC case C3N-01346, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 63.4 years (23,139 days).
Specimen C3N-01346-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5fa0f580-3461-4e51-a2ba-795cbaae9b1f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01346-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/6f96f5fd-fc2d-42fd-bb70-7f073c8f7f88

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 3; copy number 2: 15,030; copy number 3: 166; copy number 4: 37,960; copy number 5: 1,062; copy number 6: 2,629; copy number 7: 221; copy number 8: 1,000; copy number 9: 75; copy number 10: 65; copy number 11: 26; copy number 12: 45; copy number 13: 14; copy number 14: 4; copy number 15: 9; copy number 17: 22; copy number 18: 2; copy number 28: 6; copy number 38: 6; copy number 44: 5.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:20,251,905–20,620,561, 3 genes: SLIT2, SLIT2-IT1, MIR218-1.
- chr4:180,731,164–181,159,149, 2 genes: AC104803.1, LINC00290.
- chr5:159,698,586–159,937,766, 1 gene (within-gene range 0–2): LINC01847.
- chr5:176,036,593–176,203,710, 11 genes: AC139491.3, AC139491.1, FAM153B, AC139491.7, AC139491.5, AC139491.4, AC139491.6, AC139491.2, AC139491.8, AC139493.2, AC139493.1.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:39,748,514–39,892,895, 6 genes: GLIDR, BX664615.1, BX664615.2, RN7SL763P, SNORA70, CR769767.1.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 279 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,070,578–151,401,937, 21 genes, copy number 10: GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A, PSMD4, ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4.
- chr1:151,510,510–151,909,637, 31 genes, copy number 10: CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2.
- chr1:156,054,782–156,140,089, 4 genes, copy number 15: LAMTOR2, RAB25, MEX3A, LMNA.
- chr3:107,834,586–108,222,435, 6 genes, copy number 11: LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57.
- chr3:169,709,295–169,720,293, 2 genes, copy number 12: SDHDP3, RNU6-637P.
- chr6:11,183,298–11,516,466, 6 genes, copy number 12 (within-gene range 7–12): NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5.
- chr6:151,239,967–152,129,619, 15 genes, copy number 9–28 (within-gene range 4–28): AKAP12, RNU6-1247P, RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1.
- chr8:128,405,269–128,564,679, 1 gene, copy number 13: LINC00824.
- chr11:65,170,154–65,592,650, 35 genes, copy number 13–17 (within-gene range 4–17): SPDYC, PGAM1P8, AP003068.2, CAPN1, SLC22A20P, POLA2, AP000944.5, AP000944.7, CDC42EP2, DPF2, TIGD3, AP000944.1, SLC25A45, FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B, EHBP1L1.
- chr12:31,959,370–32,107,528, 6 genes, copy number 12 (within-gene range 4–12): RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1.
- chr12:124,593,181–124,725,934, 5 genes, copy number 15: AC073592.8, AC073592.2, AC073592.10, AC073592.4, AC073593.1.
- chr14:102,362,941–103,189,028, 24 genes, copy number 11–12: TECPR2, RNU6-244P, ANKRD9, MIR4309, LINC02323, RN7SL546P, RCOR1, RPL23AP11, Y_RNA, AL132801.1, TRAF3, RNU6-1316P, AMN, CDC42BPB, AL117209.1, RPL13P6, AL161669.1, EXOC3L4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12, GCSHP2, LINC00605.
- chr17:39,461,486–39,919,854, 19 genes, copy number 14–44 (within-gene range 2–44): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB.
- chr17:49,966,075–50,281,485, 22 genes, copy number 12: RNU6-1313P, DLX4, DLX3, AC009720.1, PICART1, ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4, SUMO2P7, TMEM92.
- chr17:77,086,716–77,217,101, 6 genes, copy number 10: SNHG20, SEC14L1, SCARNA16, MIR6516, RNU4-47P, CYCSP40.
- chr17:81,480,523–81,553,961, 5 genes, copy number 11: LINC01971, ACTG1, AC139149.1, FSCN2, FAAP100.
- chr19:49,331,525–49,640,143, 32 genes, copy number 9: AC011450.1, CD37, TEAD2, AC010524.1, DKKL1, AC010643.1, KASH5, PTH2, GFY, SLC17A7, PIH1D1, ALDH16A1, AC010619.1, FLT3LG, AC010619.2, RPL13A, SNORD32A, SNORD33, SNORD34, SNORD35A, RPS11, SNORD35B, MIR150, COX6CP7, FCGRT, RCN3, NOSIP, Y_RNA, PRRG2, PRR12, AC011495.2, RRAS.
- chr19:58,345,178–58,605,223, 39 genes, copy number 9: A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
